Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2KR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2KR-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation

Site of Primary (Event)

Site of Tissue

Year of Sample Collection

Age at Sample Collection (yrs)

Sample Comments

Days to Procedure Date

Days to Diagnosis

Type of Procedure

Site of Primary (Histology)

Bilateral Disease

Tumour Size (cm)

Histology

Grade/Differentiation

Pathological T

Pathological N

Number of Nodes Sampled

Number of Nodes Positive

Clinical M

Histology Comments

Fresh Frozen

Uterine

ICD-O-3

adenocarcinoma, endometrioid, NOS
8380/3

Site: Endometrium C54.1

fw 8/23/11

0

-58

Surgical resection

Uterus

NO

5.7999999999999998

Endometrioid adenocarcinoma, NOS

III

T2,NOS

N1

1

7

M0

Source: NCI Genomic Data Commons file 42757ff8-8e2d-4713-a78d-043c6ad0d933 (TCGA-DF-A2KR.7252DF0D-0D16-48DD-9484-9C4B83012927.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).